Somatic mutation profile of tumor specimen TCGA-W7-A93P-01A (aliquot TCGA-W7-A93P-01A-12D-A46P-09) from TCGA case TCGA-W7-A93P, project TCGA-CHOL (Cholangiocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Cholangiocarcinoma; Tissue or organ of origin: Extrahepatic bile duct; AJCC pathologic stage: Stage IIB; Tumor grade: G2.
Specimen TCGA-W7-A93P-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 43ac6ac2-6545-4a6b-9817-ec62e3438724.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-W7-A93P-11A (Solid Tissue Normal), aliquot TCGA-W7-A93P-11A-11D-A46P-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8f6b7faf-1159-4719-a295-181be37460d0

The open-access MAF lists 88 somatic variants for this specimen: 76 protein-altering or splice-affecting, 10 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 68, Silent 10, Frame Shift Del 3, Nonsense Mutation 2, In Frame Del 1, Nonstop Mutation 1, Intron 1, Frame Shift Ins 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACSM1 | c.880C>G p.L294V | Missense Mutation (SNP) | VAF 5/66 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.027); catalogued as COSV54633429; called by muse, mutect2
- ATR | c.196G>A p.V66M | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.997); catalogued as rs758564083, COSV100638481, COSV63386612; ClinVar: uncertain significance; called by mutect2, varscan2
- CHD2 | c.4951G>A p.G1651S | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT tolerated (0.25); PolyPhen benign (0.015); catalogued as rs1161218524, COSV67708105; called by muse, mutect2
- COL5A1 | c.1277C>G p.S426C | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.397); catalogued as rs377336135; called by muse, mutect2, varscan2
- EPB41L2 | c.337G>C p.D113H | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.503); catalogued as COSV61353821, COSV61357947; called by muse, mutect2, varscan2
- IRF1 | c.245G>C p.R82P | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55376923; called by muse, mutect2, varscan2
- MAP2K1 | c.145C>T p.R49C | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61069769; called by muse, varscan2
- MUTYH | c.1421C>T p.T474M | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs767747402, COSV58343848; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NPHS1 | c.1366C>T p.R456W | Missense Mutation (SNP) | VAF 9/100 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs772461570, COSV62286373; called by muse, mutect2, varscan2
- OR5AP2 | c.190C>G p.P64A | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.025); catalogued as rs759836075; called by mutect2, varscan2
- PPEF2 | c.2063T>G p.M688R | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.755); catalogued as rs966808583; called by muse, mutect2
- PRTG | c.1792G>A p.G598R | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66841166; called by muse, mutect2, varscan2
- RAPGEF4 | c.1315C>G p.R439G | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.615); catalogued as COSV99910409; called by muse, mutect2
- RGS1 | c.506C>T p.T169M | Missense Mutation (SNP) | VAF 9/92 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.746); catalogued as rs181973067; called by muse, mutect2, varscan2
- STAG1 | c.3060G>C p.K1020N | Missense Mutation (SNP) | VAF 8/115 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.536); catalogued as COSV52615861; called by muse, mutect2
- UBR5 | c.6161C>A p.P2054Q | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99641936; called by muse, varscan2
- ZNF780B | c.1048C>G p.R350G | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.928); catalogued as rs200803225, COSV104379547, COSV99665543; called by muse, mutect2, varscan2
- ABCA1 | c.6649T>A p.F2217I | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- AKAP6 | c.3589G>C p.E1197Q | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.69); called by muse, mutect2, varscan2
- ANGPTL1 | c.881A>G p.Y294C | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ARHGAP30 | c.2826del p.K943Sfs*61 (on ENST00000368013 / NM_001025598.2; = p.K732Sfs*61 on NM_181720.3) | Frame Shift Del (DEL) | VAF 6/52 reads (12%) | called by mutect2, pindel
- ARHGAP32 | c.454A>G p.K152E | Missense Mutation (SNP) | VAF 5/74 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.103); called by muse, mutect2
- ASCC3 | c.2550T>G p.F850L | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- ASTE1 | c.1427C>A p.T476N | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.025); called by muse, mutect2
- BCL9L | c.349G>T p.V117L | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.051); called by muse, mutect2
- BNIP5 | c.947T>A p.V316D | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.503); called by muse, mutect2
- C11orf16 | c.1354A>G p.K452E | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.201); called by muse, mutect2, varscan2
- C1orf100 | c.444A>C p.*148Yext*17 | Nonstop Mutation (SNP) | VAF 9/83 reads (11%) | called by muse, mutect2, varscan2
- C3orf20 | c.917C>G p.S306C | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.847); called by muse, mutect2
- CCDC15 | c.1892T>G p.F631C | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.906); called by muse, mutect2
- CDC37L1 | c.252T>G p.H84Q | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- CEP290 | c.2807A>C p.Q936P | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); called by muse, mutect2, varscan2
- CNOT1 | c.2931del p.I978Sfs*26 | Frame Shift Del (DEL) | VAF 8/78 reads (10%) | called by mutect2, pindel*
- COL5A1 | c.2612G>A p.G871E | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- CSMD3 | c.8883T>G p.Y2961* (on ENST00000297405 / NM_001363185.1; = p.Y2792* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 5/81 reads (6%) | called by muse, mutect2
- DCAF12L1 | c.1247T>A p.F416Y | Missense Mutation (SNP) | VAF 7/88 reads (8%) | SIFT tolerated (0.62); PolyPhen benign (0.026); called by muse, mutect2
- DHX8 | c.1691G>T p.S564I | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by mutect2, varscan2
- DISP1 | c.3527_3532del p.Y1176_H1177del | In Frame Del (DEL) | VAF 4/37 reads (11%) | called by mutect2, pindel
- DNAH11 | c.4310T>C p.L1437S | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DYRK4 | c.436C>G p.L146V | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- EFNB2 | c.128T>C p.L43P | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.587); called by muse, mutect2
- EMSY | c.2792dup p.L931Ffs*20 | Frame Shift Ins (INS) | VAF 5/55 reads (9%) | called by mutect2, pindel, varscan2
- ERCC6L | c.934A>G p.K312E | Missense Mutation (SNP) | VAF 5/82 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.289); called by muse, mutect2
- FBXO43 | c.678T>G p.N226K | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- FLG2 | c.2286G>T p.E762D | Missense Mutation (SNP) | VAF 10/132 reads (8%) | SIFT tolerated (0.4); PolyPhen benign (0.057); called by muse, mutect2
- GPATCH8 | c.1356A>C p.Q452H | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- HERC4 | c.101A>C p.K34T | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT tolerated (0.36); PolyPhen benign (0.031); called by muse, mutect2
- IBTK | c.1898A>G p.Q633R | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.652); called by muse, mutect2
- IQSEC1 | c.969C>A p.D323E | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); called by muse, mutect2
- LANCL2 | c.138G>T p.E46D | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.65); PolyPhen benign (0); called by muse, mutect2, varscan2
- LTBP4 | c.2511A>C p.E837D (on ENST00000308370 / NM_001042544.1; = p.E800D on NM_003573.2) | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- MORC1 | c.439C>T p.P147S | Missense Mutation (SNP) | VAF 13/121 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- NCOR2 | c.3398T>G p.L1133R | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NRIP2 | c.191C>A p.A64D | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.037); called by muse, mutect2
- NRIP2 | c.189A>T p.E63D | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR51B5 | c.41G>C p.G14A | Missense Mutation (SNP) | VAF 4/49 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.899); called by muse, mutect2
- PADI4 | c.1299C>G p.S433R | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- PCDH11X | c.217C>T p.P73S | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDHA2 | c.1918G>T p.A640S | Missense Mutation (SNP) | VAF 4/49 reads (8%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.023); called by muse, mutect2
- PCMTD2 | c.281T>G p.L94R | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PLEC | c.12745C>A p.P4249T (on ENST00000322810 / NM_201380.4; = p.P4139T on NM_000445.5) | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.153); called by muse, mutect2
- POMGNT2 | c.1647C>A p.N549K | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.154); called by muse, mutect2
- RABGAP1 | c.2104A>T p.M702L | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.003); called by muse, varscan2
- RAPGEF3 | c.403C>A p.L135M (on ENST00000389212; = p.L93M on NM_006105.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.28); PolyPhen probably damaging (1); called by muse, varscan2
- RWDD3 | c.763A>C p.K255Q | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT tolerated (0.5); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SAV1 | c.436_449del p.R146Sfs*4 | Frame Shift Del (DEL) | VAF 6/68 reads (9%) | called by mutect2, pindel
- SLC41A2 | c.808T>C p.Y270H | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- SULT1E1 | c.443A>G p.H148R | Missense Mutation (SNP) | VAF 8/143 reads (6%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.889); called by muse, mutect2
- SYT1 | c.1111A>C p.N371H | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2
- TENM1 | c.4586A>C p.N1529T | Missense Mutation (SNP) | VAF 7/84 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.007); called by muse, mutect2
- WDR91 | c.637G>T p.E213* | Nonsense Mutation (SNP) | VAF 9/70 reads (13%) | called by muse, mutect2, varscan2
- XIRP2 | c.5027C>A p.A1676D (on ENST00000628543; = p.A1851D on NM_152381.6) | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- XPO5 | c.584A>C p.N195T | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT tolerated (0.8); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZBBX | c.967C>G p.L323V | Missense Mutation (SNP) | VAF 8/138 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.586); called by muse, mutect2
- ZNF383 | c.701C>A p.A234D | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- ZNF528 | c.952A>G p.I318V | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.994); called by muse, mutect2
- AJM1 | c.210A>G p.P70= | Silent (SNP) | VAF 9/32 reads (28%) | catalogued as rs1415502585, COSV56033987; called by muse, mutect2, varscan2
- ASAP3 | c.1482C>A p.A494= | Silent (SNP) | VAF 4/33 reads (12%) | called by muse, mutect2, varscan2
- ASH1L | c.1800A>C p.G600= | Silent (SNP) | VAF 8/77 reads (10%) | catalogued as rs1471888055; called by muse, mutect2
- CCN4 | c.84C>A p.A28= | Silent (SNP) | VAF 8/64 reads (13%) | catalogued as COSV99136925; called by mutect2, varscan2
- CEP135 | c.3381T>G p.T1127= | Silent (SNP) | VAF 6/104 reads (6%) | called by muse, mutect2
- DMD | c.3615A>G p.E1205= | Silent (SNP) | VAF 6/76 reads (8%) | called by muse, mutect2
- INTU | c.2292T>C p.T764= | Silent (SNP) | VAF 6/76 reads (8%) | called by muse, mutect2
- NCAM1 | c.207C>A p.I69= | Silent (SNP) | VAF 6/54 reads (11%) | called by muse, varscan2
- RPS6KA5 | c.2118T>C p.S706= | Silent (SNP) | VAF 5/39 reads (13%) | called by muse, mutect2, varscan2
- RTEL1 | c.2446C>T p.L816= | Silent (SNP) | VAF 4/43 reads (9%) | called by muse, mutect2, varscan2
- CADM2 | c.62-75534T>G | Intron (SNP) | VAF 7/91 reads (8%) | called by muse, mutect2
- Metazoa_SRP | chr17:18610173 T>C | 5'Flank (SNP) | VAF 22/407 reads (5%) | called by muse, mutect2
